Somatic mutation profile of tumor specimen TCGA-AB-2846-03B (aliquot TCGA-AB-2846-03B-01W-0728-08) from TCGA case TCGA-AB-2846, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,910 days).
Specimen TCGA-AB-2846-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 508c85e6-dea2-4a45-aaf5-7de93c1f5ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2846-11B (Solid Tissue Normal), aliquot TCGA-AB-2846-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd211070-bafb-481d-871d-2e0e21614908

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1248del p.T417Lfs*6 | Frame Shift Del (DEL) | VAF 21/146 reads (14%) | catalogued as COSV55396253, COSV99854331; called by pindel*, varscan2
- ORAI1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV57491236; called by muse, varscan2
- SLCO1B1 | c.852T>A p.N284K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57006600, COSV99919383; called by muse, mutect2
- TMEM47 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs766992061, COSV52064250, COSV52066224; called by muse, mutect2, varscan2
- WT1 | c.1106_1107insT p.A370Gfs*3 | Frame Shift Ins (INS) | VAF 30/100 reads (30%) | catalogued as COSV60066438, COSV60071255, COSV60072670, COSV60072961, COSV60074589; called by pindel, varscan2
- ZFP42 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs201496236, COSV58816371, COSV58818564; called by muse, varscan2
- CUL5 | c.554-2A>T p.X185_splice | Splice Site (SNP) | VAF 2/11 reads (18%) | called by muse, mutect2
